Gene-level copy-number profile of tumor specimen TCGA-C5-A1MF-01A from TCGA case TCGA-C5-A1MF, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 49.0 years (17,911 days).
Specimen TCGA-C5-A1MF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.e6df4d2d-19cb-4418-a53c-116358016d88.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-C5-A1MF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/80c479f7-f2b9-4985-8fa0-0abf3a4faca3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,210; copy number 2: 36,629; copy number 3: 4,986; copy number 4: 6,543; copy number 5: 2,762; copy number 6: 1,704; copy number 7: 24; copy number 9: 445; copy number 10: 232; copy number 13: 265; copy number 19: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-C5-A1MF-01A-11D-A13V-01): tumor purity 0.78, ploidy 2.27, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4,269 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,017,468–187,686,628, 1,246 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:212,726,153–213,579,267, 14 genes, copy number 5: NSL1, TATDN3, AC104333.3, SPATA45, FLVCR1-DT, AC104333.1, AC104333.2, FLVCR1, AC104333.4, VASH2, ANGEL2, RPS6KC1, RPL31P13, AL592402.1.
- chr1:224,434,660–248,919,946, 606 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr3:142,801,207–198,222,513, 957 genes, copy number 9–19 (broad region; genes not listed).
- chr4:43,340,875–43,598,844, 6 genes, copy number 5: AC097451.1, AC098590.2, AC098590.1, LINC02383, AC114774.1, RN7SL691P.
- chr4:54,943,626–55,798,731, 24 genes, copy number 7 (within-gene range 1–7): AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, AC021220.2, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P.
- chr4:74,114,174–74,303,099, 1 gene, copy number 5 (within-gene range 1–5): MTHFD2L.
- chr4:74,308,470–74,589,481, 5 genes, copy number 5: EPGN, EREG, AC021180.1, AREG, AC239584.1.
- chr12:66,767–32,993,754, 832 genes, copy number 6 (broad region; genes not listed).
- chr12:68,575,858–72,186,618, 76 genes, copy number 5 (within-gene range 5–6) (broad region; genes not listed).
- chr19:8,173,272–17,075,625, 501 genes, copy number 5–6 (broad region; genes not listed).
- chr19:17,095,418–17,099,307, 1 gene, copy number 5: AC020908.3.

Autosomal genes at a single copy (total copy number 1): 6,210. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
